Somatic mutation profile of tumor specimen ALCH-B1YM-TTP1-A (aliquot ALCH-B1YM-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1YM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.2 years (21,272 days).
Specimen ALCH-B1YM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b57e374a-4274-4014-9669-b4466c066c81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YM-NB1-A (Blood Derived Normal), aliquot ALCH-B1YM-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1474156e-ed6a-4a5a-a1ee-bce3c37fe433

The open-access MAF lists 117 somatic variants for this specimen: 77 protein-altering or splice-affecting, 26 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 26, Intron 6, Nonsense Mutation 3, 3'Flank 2, 5'Flank 2, 3'UTR 2, Frame Shift Del 1, Splice Site 1, RNA 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 28/191 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP4 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs927075560; called by muse, mutect2, varscan2
- AKR1D1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV54335953; called by muse, varscan2
- ANKRD30B | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.982); catalogued as rs1399556740; called by muse, mutect2
- ANP32A | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs773212886; called by muse, mutect2
- BIRC6 | c.1775A>G p.D592G | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs1241984736; called by muse, mutect2, varscan2
- CACNA1F | c.4699G>C p.D1567H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD1514230, COSV59905250; called by muse, mutect2, varscan2
- CCDC169 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.453); catalogued as rs576535002, COSV53485393; called by muse, mutect2
- CEACAM7 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV50073699; called by muse, mutect2, varscan2
- COL24A1 | c.1898G>C p.G633A | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65302734; called by muse, mutect2, varscan2
- DOCK4 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV70234039; called by muse, mutect2
- ELMOD1 | c.18-1G>A p.X6_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as rs1485875214, COSV99759868; called by muse, mutect2
- ESPL1 | c.3590G>A p.R1197H | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1426845160; called by muse, mutect2, varscan2
- FAM234B | c.19A>T p.R7W | Missense Mutation (SNP) | VAF 52/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1310683205; called by muse, mutect2, varscan2
- FIGNL1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV63553956; called by muse, mutect2
- FRAS1 | c.8252C>T p.S2751F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV53602308; called by muse, mutect2, varscan2
- GCK | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100356983; called by muse, mutect2
- HNRNPM | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV100335006; called by muse, mutect2
- KLK1 | c.478A>G p.S160G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs757985620; called by mutect2, varscan2
- LILRB5 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.245); catalogued as rs1449956390, COSV100300605; called by muse, mutect2, varscan2
- LRP1B | c.13613C>A p.P4538Q | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs779646780, COSV67245099; called by muse, mutect2
- NFE2L2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV67960190; called by muse, mutect2
- OR2M5 | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV63546549, COSV63546601; called by muse, mutect2, varscan2
- PCDH10 | c.2330C>A p.A777E | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.573); catalogued as rs750744037, COSV99994882; called by muse, mutect2
- PCDH11X | c.2243G>T p.R748I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100010160, COSV53479780; called by muse, mutect2, varscan2
- PCDHGB3 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 73/653 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.053); catalogued as COSV53918082; called by muse, mutect2, varscan2
- PEG3 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs746531138, COSV55642004; called by muse, mutect2, varscan2
- PTBP2 | c.458G>T p.R153L (on ENST00000426398 / NM_001300986.2; = p.R145L on NM_021190.4) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV64624832, COSV64624909; called by muse, mutect2, varscan2
- SOX14 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs1012345183; called by muse, mutect2
- SPINK8 | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV71285441; called by muse, mutect2
- SPTA1 | c.3743G>T p.R1248L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63753987; called by muse, mutect2, varscan2
- TAF11 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 22/475 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV63543286; called by muse, mutect2
- TG | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV104377518; called by muse, mutect2
- TNC | c.5548G>T p.V1850L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV60787282; called by muse, mutect2, varscan2
- TP63 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 241/463 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM083196, COSV53197460, COSV53207297, COSV53220659; called by muse, mutect2, varscan2
- USP17L2 | c.1353C>A p.N451K | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.914); catalogued as rs371227729; called by muse, mutect2
- AGBL1 | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by mutect2, varscan2
- ATP2B1 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2
- ATP2C1 | c.711A>C p.E237D | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.169); called by muse, mutect2
- BRWD3 | c.4072C>A p.L1358I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2
- CHD7 | c.6041A>T p.Y2014F | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CMPK2 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); called by muse, mutect2
- DDX46 | c.3005A>G p.K1002R | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.042); called by muse, mutect2
- DOT1L | c.2957A>G p.Q986R | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.736); called by muse, mutect2
- FBN2 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 31/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FNDC1 | c.5419A>G p.K1807E | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GFOD2 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HAPLN1 | c.181T>C p.C61R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR1B | c.14del p.G5Vfs*66 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, varscan2
- KIF21A | c.2129C>G p.S710* (on ENST00000361418 / NM_001378440.1; = p.S697* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- KIF5C | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLRC3 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- LAMP2 | c.1232A>G p.*411Wext*6 | Nonstop Mutation (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- LRRC15 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2
- MCU | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MTDH | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, varscan2
- NBR1 | c.2554A>G p.I852V | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDT12 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); called by muse, mutect2
- P2RY14 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PDE3A | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.069); called by muse, mutect2
- PHACTR3 | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PHLPP1 | c.4658T>C p.I1553T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PIANP | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 64/599 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- PRPF38B | c.265A>T p.I89F | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPK2 | c.442A>T p.K148* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | called by muse, varscan2
- SEC24D | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SIPA1L2 | c.4921G>A p.E1641K | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMARCA2 | c.3328A>G p.K1110E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); called by muse, varscan2
- TMEM132D | c.1611G>C p.Q537H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOX3 | c.569T>C p.L190S | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.203); called by muse, mutect2
- TRIM64C | c.267C>A p.D89E | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- TTC37 | c.1465G>T p.D489Y | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TUBB2B | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); called by muse, mutect2
- UHRF1 | c.235C>T p.L79F (on ENST00000612630 / NM_001290050.1; = p.L92F on NM_013282.4) | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZCCHC8 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF644 | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- ZNF658 | c.2458C>T p.H820Y | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ADSS1 | c.888C>T p.G296= | Silent (SNP) | VAF 48/505 reads (10%) | catalogued as rs553526202, COSV58274568; ClinVar: likely benign; called by muse, mutect2
- APBA2 | c.2010G>A p.Q670= | Silent (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- CACNA1F | c.2496C>A p.L832= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as rs782068049; called by muse, mutect2, varscan2
- CASP2 | c.684T>C p.T228= | Silent (SNP) | VAF 30/324 reads (9%) | catalogued as rs749885591; called by muse, mutect2
- CIC | c.2061C>T p.A687= | Silent (SNP) | VAF 125/660 reads (19%) | catalogued as rs1327917693; called by muse, mutect2, varscan2
- DCC | c.868T>C p.L290= | Silent (SNP) | VAF 45/272 reads (17%) | catalogued as rs1332947405; called by muse, varscan2
- DNAH12 | c.6711A>G p.E2237= (on ENST00000351747; = p.E2256= on NM_001366028.2) | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- DPP10 | c.2019G>C p.V673= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV59710304; called by muse, mutect2, varscan2
- ERICH3 | c.1314G>A p.V438= | Silent (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- FAM135B | c.1113G>A p.T371= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs745439659, COSV52724629; called by muse, mutect2
- IGHE | c.708G>T p.T236= | Silent (SNP) | VAF 35/267 reads (13%) | catalogued as rs546504217; called by muse, mutect2, varscan2
- ITPK1 | c.81C>T p.F27= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs1165152607; called by muse, mutect2, varscan2
- MPDZ | c.1854C>T p.I618= | Silent (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2
- MROH7 | c.1422C>G p.L474= | Silent (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- OR2G2 | c.366C>A p.S122= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV60739871; called by muse, mutect2, varscan2
- PCDHGA9 | c.429C>T p.N143= | Silent (SNP) | VAF 11/175 reads (6%) | catalogued as rs1022563452, COSV53899236; called by muse, mutect2
- PI4KA | c.4716G>A p.V1572= | Silent (SNP) | VAF 35/298 reads (12%) | called by muse, varscan2
- PPP1R9B | c.1608G>A p.A536= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as rs754230612; called by muse, mutect2, varscan2
- PRKAG2 | c.600A>T p.T200= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- PROP1 | c.295C>A p.R99= | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as CM012797; called by muse, mutect2, varscan2
- SLC38A7 | c.948G>A p.S316= | Silent (SNP) | VAF 26/280 reads (9%) | catalogued as rs765145675; called by muse, mutect2
- SPZ1 | c.672A>G p.Q224= | Silent (SNP) | VAF 23/171 reads (13%) | catalogued as rs755914475; called by muse, mutect2, varscan2
- TARBP1 | c.3840C>T p.F1280= | Silent (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- TNR | c.615G>T p.P205= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs1030073087, COSV54893067, COSV54896359; called by muse, mutect2, varscan2
- TTC28 | c.5007C>T p.I1669= | Silent (SNP) | VAF 12/329 reads (4%) | called by muse, mutect2
- ZNF728 | c.933C>A p.P311= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2211+1652G>T | Intron (SNP) | VAF 33/231 reads (14%) | called by muse, mutect2, varscan2
- CSNK2B | c.175+34C>T | Intron (SNP) | VAF 12/160 reads (8%) | catalogued as rs772852306, COSV63263681; called by muse, mutect2
- DNAJA4 | c.132+749T>G | Intron (SNP) | VAF 18/148 reads (12%) | called by muse, varscan2
- EMX1 | c.521-17C>T | Intron (SNP) | VAF 16/447 reads (4%) | called by muse, mutect2
- HBP1 | c.1385+225A>C | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as rs1223456977; called by muse, mutect2
- LIMD1 | c.1824+30G>A | Intron (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- LINC01193 | n.726G>C | RNA (SNP) | VAF 14/251 reads (6%) | called by muse, mutect2
- MIR7162 | chr10:30364814 G>A | 3'Flank (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- PPP1R1B | chr17:39622101 A>G | 5'Flank (SNP) | VAF 15/195 reads (8%) | called by muse, mutect2
- PVALEF | c.-586G>A | 5'UTR (SNP) | VAF 20/280 reads (7%) | catalogued as rs747297362; called by muse, mutect2
- SHROOM4 | c.*1151A>T | 3'UTR (SNP) | VAF 11/140 reads (8%) | catalogued as rs895852465; called by muse, mutect2
- SYT14 | chr1:210162816 T>C | 3'Flank (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- TNS2 | chr12:53049097 C>T | 5'Flank (SNP) | VAF 7/43 reads (16%) | called by muse, varscan2
- VAPB | c.*1999G>T | 3'UTR (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
